Somatic mutation profile of tumor specimen C3L-00769-01 (aliquot CPT0026530009) from CPTAC case C3L-00769, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.6 years (20,660 days).
Specimen C3L-00769-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc3294cf-650b-4480-bbe2-53572b603733.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00769-71 (Blood Derived Normal), aliquot CPT0026590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57dffbc8-22ad-4580-8d27-102365559aae

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 27/278 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- ASMTL | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771456500; called by muse, varscan2
- BEND3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs782731122, COSV64681450; called by muse, mutect2
- CD3G | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374176598; called by muse, mutect2, varscan2
- CDH20 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs758510987, COSV53004764, COSV53005466; called by muse, mutect2, varscan2
- CDKL1 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs148712966, COSV53583351; called by muse, mutect2
- CLVS1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as rs1460252234, COSV57974192; called by muse, mutect2, varscan2
- CNTNAP1 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs746268826; called by muse, varscan2
- CTCF | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50462744; called by muse, mutect2, varscan2
- DIRAS2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs778547186; called by muse, mutect2, varscan2
- FEV | c.328_330del p.D110del | In Frame Del (DEL) | VAF 41/298 reads (14%) | catalogued as rs1186562791; called by mutect2, pindel, varscan2
- GMIP | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52554701; called by muse, mutect2, varscan2
- HSPA2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV55968812; called by muse, mutect2, varscan2
- KRT31 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs758246862; called by muse, mutect2
- MAN2A2 | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs777153370; called by muse, mutect2, varscan2
- MMUT | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs766529896, COSV51272223; called by muse, mutect2
- NOTUM | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as rs776143547, COSV101293744; called by muse, mutect2, varscan2
- OTOL1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200049709, COSV100019855, COSV60007961; called by muse, mutect2
- PCDHA9 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs555417773, COSV65334252; called by muse, mutect2, varscan2
- RBBP7 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV58113635; called by muse, mutect2, varscan2
- SERTAD2 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as rs146983633; called by muse, mutect2, varscan2
- SHROOM4 | c.3566G>T p.G1189V | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV56785390; called by muse, mutect2, varscan2
- SPHKAP | c.4790C>T p.P1597L (on ENST00000392056 / NM_001142644.2; = p.P1568L on NM_030623.3) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748254156, COSV60867531; called by muse, mutect2, varscan2
- ZNF444 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs748484904; called by muse, mutect2, varscan2
- ZNF730 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as COSV74168350; called by muse, mutect2, varscan2
- C19orf38 | c.506-1G>C p.X169_splice | Splice Site (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- CCDC77 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL13A1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- IGFBP3 | c.651G>C p.M217I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KMT2D | c.10137_10138del p.K3380Afs*42 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- LRP1 | c.6908C>T p.T2303M | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUBP1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH19 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PCDHB4 | c.1192A>G p.N398D | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIGG | c.1598G>T p.G533V (on ENST00000453061 / NM_001127178.3; = p.G525V on NM_017733.4) | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- PTEN | c.35del p.N12Tfs*12 | Frame Shift Del (DEL) | VAF 104/360 reads (29%) | called by mutect2, pindel, varscan2
- SPART | c.842_846del p.D281Vfs*15 | Frame Shift Del (DEL) | VAF 32/233 reads (14%) | called by pindel, varscan2
- SUCLG1 | c.331del p.T111Qfs*57 | Frame Shift Del (DEL) | VAF 41/285 reads (14%) | called by mutect2, pindel*, varscan2
- TNXB | c.6983G>T p.S2328I (on ENST00000647633; = p.S2081I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- WWC3 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ATXN2L | c.3072C>T p.I1024= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs771658704, COSV57366241; called by muse, mutect2, varscan2
- CRH | c.357G>A p.L119= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs775986889; called by muse, mutect2, varscan2
- CSNK1D | c.156G>A p.E52= | Silent (SNP) | VAF 84/435 reads (19%) | called by muse, mutect2, varscan2
- DNAH7 | c.8706C>A p.I2902= | Silent (SNP) | VAF 25/175 reads (14%) | called by muse, mutect2, varscan2
- FAM47A | c.981G>A p.P327= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as rs989077140, COSV60498807; called by muse, mutect2, varscan2
- IKBIP | c.162G>A p.T54= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs561040529; called by muse, mutect2, varscan2
- LATS2 | c.858C>T p.Y286= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1439036431; called by muse, mutect2, varscan2
- LNX1 | c.828G>A p.K276= (on ENST00000263925 / NM_001126328.3; = p.K180= on NM_032622.2) | Silent (SNP) | VAF 42/237 reads (18%) | catalogued as COSV99820181; called by muse, mutect2, varscan2
- LRP1B | c.18C>A p.L6= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs139525868, COSV101257740; called by muse, mutect2
- MPRIP | c.1074C>T p.D358= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs764009264, COSV59045781; called by muse, mutect2, varscan2
- ZNF425 | c.891C>T p.R297= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as rs777120036; called by muse, mutect2, varscan2
- RALGDS | c.2211+25T>C | Intron (SNP) | VAF 50/207 reads (24%) | catalogued as rs983275823; called by muse, mutect2, varscan2
